Somatic mutation profile of tumor specimen TCGA-BJ-A3PU-01A (aliquot TCGA-BJ-A3PU-01A-11D-A21Z-08) from TCGA case TCGA-BJ-A3PU, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 52.0 years (19,007 days).
Specimen TCGA-BJ-A3PU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58fa3d87-84bb-405d-a384-2c9ce028fe46.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A3PU-10A (Blood Derived Normal), aliquot TCGA-BJ-A3PU-10A-01D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c460b0b-35fa-43aa-adda-9fd03ee9efbc

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BGN | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs782083006, COSV59035922; called by muse, mutect2, varscan2
- CNOT1 | c.6484C>T p.P2162S | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55323276; called by muse, mutect2, varscan2
- HLCS | c.1561C>G p.L521V | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.34); catalogued as rs1244900266, COSV60799218; called by muse, mutect2
- KAT8 | c.1126T>C p.F376L | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as COSV54899687; called by muse, mutect2, varscan2
- LIN54 | c.1742C>G p.P581R | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61203196; called by muse, mutect2, varscan2
- SPTAN1 | c.3156-1G>A p.X1052_splice | Splice Site (SNP) | VAF 4/21 reads (19%) | catalogued as COSV63990185; called by muse, mutect2
- TMEM132D | c.467G>T p.W156L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70624180; called by muse, mutect2, varscan2
- TNIK | c.2978A>T p.D993V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); catalogued as COSV52699184; called by muse, mutect2, varscan2
- TSPAN8 | c.684G>T p.M228I | Missense Mutation (SNP) | VAF 58/151 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.359); catalogued as COSV56080972; called by muse, mutect2, varscan2
- TTC39C | c.304G>A p.A102T (on ENST00000317571 / NM_001135993.2; = p.A41T on NM_153211.4) | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.87); PolyPhen benign (0.079); catalogued as COSV58221736; called by muse, mutect2, varscan2
- FAM76A | c.893_894del p.S298* | Frame Shift Del (DEL) | VAF 17/39 reads (44%) | called by mutect2, pindel, varscan2
- CHST8 | c.747C>T p.S249= | Silent (SNP) | VAF 10/136 reads (7%) | catalogued as COSV52864150; called by muse, mutect2
- CSRNP3 | c.1521C>T p.S507= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs766392480, COSV100086430, COSV58787000; called by muse, mutect2, varscan2
- RSPH10B | c.1662T>C p.N554= | Silent (SNP) | VAF 26/99 reads (26%) | catalogued as rs1309137079, COSV61755457; called by muse, mutect2, varscan2
- RXRA | c.1125C>T p.L375= | Silent (SNP) | VAF 25/50 reads (50%) | catalogued as rs773547211, COSV62685718; called by muse, mutect2, varscan2
